Somatic mutation profile of tumor specimen BA2181D (aliquot aq-BA2181D) from BEATAML1.0 case 2147, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.6 years (25,778 days).
Specimen BA2181D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483db2cc-1aff-48da-a594-fb385d7e0c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2208D (Solid Tissue Normal), aliquot aq-BA2208D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdba55c3-8f58-459f-9981-11d6c5bb1fa9

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, 5'Flank 2, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.405G>C p.R135S (on ENST00000344691 / NM_001001890.3; = p.R162S on NM_001754.5) | Missense Mutation (SNP) | VAF 123/130 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519749, COSV100277991, COSV55879245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP128 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs751491530, COSV55368687; called by muse, mutect2, varscan2
- ERBB4 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs532377012, COSV53542123; called by muse, mutect2, varscan2
- FLT3 | c.1796_1797insCGCTCCCCTAGAATATGAA p.D600Afs*7 | Frame Shift Ins (INS) | VAF 34/79 reads (43%) | catalogued as COSV54043047, COSV54074386, COSV54075413; called by muse*, mutect2, varscan2*
- DOCK1 | c.2569dup p.E857Gfs*70 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- KLHL13 | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- NCAM1 | c.491-1G>C p.X164_splice | Splice Site (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.1575G>T p.L525F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC15A5 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SMARCAD1 | c.1005del p.A336Hfs*35 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- TBC1D8B | c.2399A>G p.D800G | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ATP11C | c.3304C>T p.L1102= | Silent (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- FGD5 | c.3774C>A p.T1258= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- MYBPC2 | c.2565C>T p.G855= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as COSV63096526; called by muse, mutect2, varscan2
- SLC25A31 | c.849C>T p.G283= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs907411784, COSV55420218; called by muse, mutect2, varscan2
- SLC35A2 | c.1158G>T p.L386= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TSEN34 | c.67C>A p.R23= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- LIPC | c.88+4570C>A | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- RHOBTB2 | chr8:22994590 G>A | 5'Flank (SNP) | VAF 14/31 reads (45%) | catalogued as rs1202325516; called by muse, mutect2, varscan2
- TK1 | chr17:78187090 C>A | 5'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
